Somatic mutation profile of tumor specimen TCGA-13-0887-01A (aliquot TCGA-13-0887-01A-01W-0420-08) from TCGA case TCGA-13-0887, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.9 years (15,669 days).
Specimen TCGA-13-0887-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47df10e5-13ef-44be-9dec-381779518fad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0887-10A (Blood Derived Normal), aliquot TCGA-13-0887-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1c61852-7bbd-4d2c-8cd0-89b09cc70e70

The open-access MAF lists 149 somatic variants for this specimen: 107 protein-altering or splice-affecting, 41 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 41, Splice Site 5, Nonsense Mutation 5, Frame Shift Del 4, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 279/495 reads (56%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.2099G>C p.G700A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60682114; called by muse, mutect2, varscan2
- ADCY4 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.247); catalogued as COSV99353588; called by muse, mutect2, varscan2
- ADGRE2 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 153/357 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.939); catalogued as rs143530914, COSV59692232; called by muse, mutect2, varscan2
- ADGRG4 | c.7726G>C p.D2576H | Missense Mutation (SNP) | VAF 94/1209 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99797560; called by muse, mutect2
- ADI1 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV59376458; called by muse, mutect2
- AHCTF1 | c.4337T>A p.L1446H (on ENST00000366508; = p.L1420H on NM_015446.5) | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as COSV58247032; called by muse, mutect2, varscan2
- AKAP9 | c.9526G>T p.E3176* (on ENST00000359028; = p.E3152* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 118/246 reads (48%) | catalogued as COSV62341059; called by muse, mutect2, varscan2
- AOX1 | c.1141T>G p.L381V | Missense Mutation (SNP) | VAF 236/595 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV65980613; called by muse, mutect2, varscan2
- ATP11B | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV60026984; called by muse, mutect2, varscan2
- BCAT2 | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60271975; called by muse, mutect2, varscan2
- BIN2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 166/752 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs555115486, COSV57204345; called by muse, mutect2, varscan2
- BTRC | c.196C>T p.P66S (on ENST00000370187 / NM_033637.4; = p.P30S on NM_003939.5) | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV64560693; called by muse, mutect2, varscan2
- C7orf57 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1317008462, COSV62362134; called by muse, mutect2, varscan2
- CCDC39 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 38/127 reads (30%) | catalogued as COSV56480169; called by muse, mutect2, varscan2
- CCKBR | c.979G>C p.A327P | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58099503; called by muse, mutect2, varscan2
- CDH6 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54063755, COSV54065976; called by muse, mutect2, varscan2
- CDH8 | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV100184704; called by muse, mutect2
- CEP350 | c.6620C>G p.P2207R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV62599836; called by muse, mutect2, varscan2
- CHD1 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV52338203; called by muse, mutect2, varscan2
- CHD1L | c.2616-1G>A p.X872_splice | Splice Site (SNP) | VAF 74/284 reads (26%) | catalogued as rs782291956, COSV63613113; called by muse, mutect2, varscan2
- CMYA5 | c.4565T>G p.V1522G | Missense Mutation (SNP) | VAF 146/356 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs746462149, COSV71404530; called by muse, mutect2, varscan2
- COL5A2 | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs149064715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPZ | c.1444G>A p.E482K (on ENST00000360986 / NM_001014447.3; = p.E471K on NM_003652.3) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs771666220, COSV100249379; called by muse, mutect2, varscan2
- CRELD1 | c.1025T>A p.I342N | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV55976596; called by muse, mutect2, varscan2
- CSMD3 | c.5402T>G p.F1801C (on ENST00000297405 / NM_001363185.1; = p.F1697C on NM_052900.3) | Missense Mutation (SNP) | VAF 10/326 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99851982; called by muse, mutect2
- CTBP1 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52072348; called by muse, mutect2, varscan2
- DOCK7 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV51998703, COSV52008306; called by muse, mutect2, varscan2
- DUSP19 | c.532T>C p.S178P | Missense Mutation (SNP) | VAF 74/818 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV61192942; called by muse, mutect2
- EFEMP1 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62615354; called by muse, mutect2, varscan2
- EHMT2 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 364/453 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64993621; called by muse, mutect2, varscan2
- EPC2 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 168/348 reads (48%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.983); catalogued as COSV51541384; called by muse, mutect2, varscan2
- ETV7 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 231/359 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60316297, COSV60317125; called by muse, mutect2, varscan2
- FASTK | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99880055; called by muse, varscan2
- GPATCH8 | c.1618G>C p.V540L | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100132958; called by muse, mutect2
- GPR101 | c.231C>G p.D77E | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53237825; called by muse, mutect2, varscan2
- GPT | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99477918; called by muse, mutect2, varscan2
- HAS2 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 101/652 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as COSV58262532; called by muse, mutect2, varscan2
- HCAR2 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs775536264, COSV100186705; called by muse, mutect2, varscan2
- HGF | c.1609C>A p.P537T | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.932); catalogued as COSV99738952; called by muse, mutect2, varscan2
- HUWE1 | c.9097-1G>T p.X3033_splice | Splice Site (SNP) | VAF 409/864 reads (47%) | catalogued as COSV53338064; called by muse, mutect2, varscan2
- IFT57 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52708608; called by muse, mutect2, varscan2
- IGLV2-11 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 411/544 reads (76%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.035); catalogued as rs1359791451; called by muse, mutect2, varscan2
- IPPK | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.119); catalogued as rs150868938; called by muse, mutect2, varscan2
- IQCB1 | c.179A>T p.Q60L | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100182208; called by muse, mutect2
- IQUB | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV61237877; called by muse, mutect2, varscan2
- IRGC | c.390C>A p.D130E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV54983276; called by muse, mutect2, varscan2
- ITPKB | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 260/599 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV55258436; called by muse, mutect2, varscan2
- KAT6B | c.4118A>G p.E1373G | Missense Mutation (SNP) | VAF 314/678 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.04); catalogued as rs373140884; called by muse, mutect2, varscan2
- KCNA2 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV60369352; called by muse, mutect2, varscan2
- KDM4B | c.1870C>A p.L624M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.391); catalogued as COSV99347728; called by muse, varscan2
- LRBA | c.7372A>G p.I2458V | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as rs754778401, COSV63951341; called by muse, mutect2, varscan2
- MED13L | c.6038C>T p.P2013L | Missense Mutation (SNP) | VAF 52/627 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.583); catalogued as COSV99930604; called by muse, mutect2
- MFSD2B | c.737T>A p.I246N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV57854156; called by muse, varscan2
- MLF2 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 30/626 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs748803004, COSV99180126; called by muse, mutect2
- MOK | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs971063841, COSV51963723; called by muse, mutect2, varscan2
- MYLK | c.2282T>A p.L761H | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60606388; called by muse, mutect2, varscan2
- MYO7A | c.5211G>C p.K1737N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV68683867; called by muse, mutect2, varscan2
- NAA20 | c.208T>C p.W70R | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100131875; called by muse, mutect2, varscan2
- NEB | c.19706G>A p.G6569E | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV50850657; called by muse, mutect2, varscan2
- OGA | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 48/107 reads (45%) | catalogued as COSV63381176; called by muse, mutect2, varscan2
- PABPN1 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV53729281; called by muse, mutect2, varscan2
- PAPPA2 | c.2709T>G p.C903W | Missense Mutation (SNP) | VAF 72/455 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62774754; called by muse, mutect2, varscan2
- PCDHAC1 | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV99170626; called by muse, mutect2, varscan2
- PITPNM3 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458059596, COSV52593693; called by muse, mutect2, varscan2
- POLR2B | c.2281A>T p.T761S | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58899098; called by muse, mutect2, varscan2
- PRKCE | c.590A>C p.Q197P | Missense Mutation (SNP) | VAF 93/765 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60314607; called by muse, mutect2, varscan2
- PRSS27 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 29/36 reads (81%) | catalogued as COSV100234628; called by muse, mutect2, varscan2
- PUM1 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1443162687, COSV99929152; called by muse, mutect2
- PWWP3B | c.1234A>T p.S412C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV61798692; called by muse, mutect2, varscan2
- RALGAPA2 | c.2001A>T p.K667N | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52491634; called by muse, mutect2, varscan2
- RAPGEF1 | c.2482G>T p.G828W | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs539844465, COSV64698439; called by muse, mutect2, varscan2
- RIOK3 | c.1366A>C p.K456Q | Missense Mutation (SNP) | VAF 182/466 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV59772396; called by muse, mutect2, varscan2
- RNASE11 | c.517A>T p.S173C | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60087333; called by muse, mutect2, varscan2
- RNF150 | c.868G>T p.V290F | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100154439; called by muse, mutect2
- SDK2 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 107/129 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs147112459; called by muse, mutect2, varscan2
- SEMA5A | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as COSV101228789; called by muse, mutect2
- SGSM3 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50651377; called by muse, mutect2, varscan2
- SLC12A8 | c.97A>C p.M33L | Missense Mutation (SNP) | VAF 169/220 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58863935, COSV58864163; called by muse, mutect2, varscan2
- SLC15A1 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV64730392; called by muse, mutect2
- SLC39A10 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 12/456 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100660796; called by muse, mutect2
- SLC39A10 | c.1832A>G p.D611G | Missense Mutation (SNP) | VAF 12/459 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs1461379947, COSV100660797; called by muse, mutect2
- SORL1 | c.1397A>G p.N466S | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs377405996; called by muse, mutect2, varscan2
- ST7 | c.642A>T p.E214D | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.216); catalogued as COSV55381469; called by muse, mutect2, varscan2
- STK31 | c.1756A>G p.S586G | Missense Mutation (SNP) | VAF 53/377 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63454605; called by muse, mutect2, varscan2
- STK33 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 345/749 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as rs199852553; called by muse, mutect2, varscan2
- SUPT3H | c.955C>G p.R319G (on ENST00000371460 / NM_181356.3; = p.R308G on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/817 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV100178613; called by muse, mutect2
- SYNM | c.1783G>A p.G595S | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV100153128; called by muse, mutect2
- THAP2 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs747178505, COSV57348169; called by muse, mutect2, varscan2
- TNS3 | c.307G>T p.V103F | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1484797389, COSV100236778; called by muse, mutect2
- TP53BP2 | c.2194T>A p.S732T (on ENST00000343537 / NM_001031685.3; = p.S603T on NM_005426.2) | Missense Mutation (SNP) | VAF 37/890 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.253); catalogued as COSV100636888; called by muse, mutect2
- TTN | c.26517G>C p.Q8839H (on ENST00000591111; = p.Q7912H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/608 reads (28%) | PolyPhen benign (0.382); catalogued as COSV59934752; called by muse, mutect2, varscan2
- TUBA4A | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 130/748 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV50277811; called by muse, mutect2, varscan2
- UBL4B | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV61944243; called by muse, mutect2, varscan2
- UGT1A10 | c.111C>G p.H37Q | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60833836; called by muse, mutect2, varscan2
- VWA5A | c.2023G>T p.G675C | Missense Mutation (SNP) | VAF 32/617 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as COSV100827987, COSV64412776; called by muse, mutect2
- ZNF266 | c.1173A>T p.R391S | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV100749462; called by muse, mutect2
- ZNF560 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs1215510284, COSV100039186; called by muse, mutect2
- ZSCAN21 | c.594T>A p.D198E | Missense Mutation (SNP) | VAF 122/257 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as COSV52849676; called by muse, mutect2, varscan2
- ADGRV1 | c.1718_1763del p.G573Efs*11 | Frame Shift Del (DEL) | VAF 64/130 reads (49%) | called by mutect2, pindel
- ALMS1 | c.1674_1687del p.P560Dfs*9 | Frame Shift Del (DEL) | VAF 25/228 reads (11%) | called by mutect2, pindel
- BNIP5 | c.1585_1603+16del p.X529_splice | Splice Site (DEL) | VAF 112/317 reads (35%) | called by mutect2, pindel
- CACNA1C | c.3829-18_3839del p.X1277_splice | Splice Site (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel
- NCOR1 | c.6839_6868del p.E2280_M2290delinsV | In Frame Del (DEL) | VAF 17/118 reads (14%) | called by mutect2, pindel
- PKD2L2 | c.651_661del p.D217Efs*9 | Frame Shift Del (DEL) | VAF 13/110 reads (12%) | called by mutect2, pindel, varscan2
- SCN1A | c.2411del p.N804Tfs*14 (on ENST00000303395 / NM_001202435.3; = p.N793Tfs*14 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/127 reads (41%) | called by mutect2, pindel, varscan2
- SFXN3 | c.444-14_445del p.X148_splice | Splice Site (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel
- ADAM22 | c.2720A>G p.*907= (on ENST00000265727 / NM_001324420.2; = p.*871= on NM_016351.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/546 reads (7%) | catalogued as COSV99718770; called by muse, mutect2
- ARHGEF16 | c.1095G>A p.E365= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV65681493; called by muse, mutect2, varscan2
- BCS1L | c.1249C>T p.L417= | Silent (SNP) | VAF 12/271 reads (4%) | catalogued as COSV99829273; called by muse, mutect2
- BHLHE40 | c.1200G>T p.L400= | Silent (SNP) | VAF 11/244 reads (5%) | catalogued as COSV99848341; called by muse, mutect2
- BRD1 | c.336C>G p.A112= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99350499; called by muse, mutect2
- C12orf42 | c.639C>T p.A213= | Silent (SNP) | VAF 60/80 reads (75%) | catalogued as rs919261657, COSV59380129; called by muse, varscan2
- CD180 | c.303T>C p.H101= | Silent (SNP) | VAF 96/607 reads (16%) | catalogued as COSV56517202; called by muse, mutect2, varscan2
- CILP | c.222G>T p.L74= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV56022611; called by muse, mutect2, varscan2
- CTNND2 | c.588A>G p.R196= | Silent (SNP) | VAF 106/360 reads (29%) | catalogued as COSV58872302; called by muse, mutect2, varscan2
- DNAH1 | c.7308C>T p.Y2436= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV101327404; called by muse, mutect2, varscan2
- EGFLAM | c.2430C>T p.C810= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV59295459; called by muse, mutect2, varscan2
- FZD2 | c.1545G>A p.S515= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV59528351; called by muse, mutect2, varscan2
- GALNTL5 | c.1077A>G p.G359= | Silent (SNP) | VAF 95/333 reads (29%) | catalogued as COSV67179537; called by muse, mutect2, varscan2
- KCNAB1 | c.189G>T p.L63= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as rs757856229, COSV67484634; called by muse, mutect2, varscan2
- KIF21A | c.2889A>G p.K963= (on ENST00000361418 / NM_001378440.1; = p.K950= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 204/454 reads (45%) | catalogued as rs1161324213, COSV62768490; called by muse, mutect2, varscan2
- KIF21B | c.3057C>G p.S1019= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as COSV59754128; called by muse, mutect2, varscan2
- KIF21B | c.1974G>T p.R658= | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as COSV100145352; called by muse, mutect2
- MED13L | c.6039C>T p.P2013= | Silent (SNP) | VAF 53/625 reads (8%) | catalogued as COSV99930603; called by muse, mutect2
- MYLK3 | c.2019C>T p.F673= | Silent (SNP) | VAF 137/328 reads (42%) | catalogued as rs373988254; called by muse, mutect2, varscan2
- NAA25 | c.522G>A p.L174= | Silent (SNP) | VAF 64/217 reads (29%) | catalogued as rs774172762, COSV55702749, COSV55708015; called by muse, mutect2, varscan2
- OR2T10 | c.129T>C p.I43= | Silent (SNP) | VAF 8/231 reads (3%) | catalogued as COSV100393870; called by muse, mutect2
- OR7G1 | c.843C>A p.V281= | Silent (SNP) | VAF 44/514 reads (9%) | catalogued as COSV53317294; called by muse, mutect2
- PRSS27 | c.384G>C p.V128= | Silent (SNP) | VAF 29/35 reads (83%) | catalogued as COSV100234631; called by muse, mutect2, varscan2
- PTPRK | c.3909T>A p.S1303= (on ENST00000368215 / NM_001291984.2; = p.S1304= on NM_002844.4) | Silent (SNP) | VAF 174/215 reads (81%) | catalogued as COSV63893078; called by muse, mutect2, varscan2
- RASL11B | c.9C>A p.L3= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV99954558; called by muse, mutect2, varscan2
- RCN3 | c.318C>T p.I106= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs576658208, COSV54541427, COSV54542839; called by muse, mutect2
- SLC7A14 | c.72C>A p.S24= | Silent (SNP) | VAF 98/156 reads (63%) | catalogued as COSV51579207; called by muse, mutect2, varscan2
- SLC9A1 | c.2106C>T p.G702= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV56051971; called by muse, mutect2
- SPATA31E1 | c.951C>A p.G317= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs201064219, COSV57790049; called by muse, mutect2, varscan2
- STXBP3 | c.756G>C p.L252= | Silent (SNP) | VAF 151/329 reads (46%) | catalogued as COSV64181751; called by muse, mutect2, varscan2
- SYNE2 | c.19131T>G p.S6377= | Silent (SNP) | VAF 77/160 reads (48%) | catalogued as COSV59942657; called by muse, mutect2, varscan2
- TARBP1 | c.3594T>C p.A1198= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as COSV50180030; called by muse, mutect2
- TENM4 | c.6450G>A p.R2150= | Silent (SNP) | VAF 11/273 reads (4%) | called by muse, mutect2
- TM2D1 | c.30T>G p.S10= | Silent (SNP) | VAF 63/162 reads (39%) | catalogued as COSV53905666; called by muse, mutect2, varscan2
- TMC2 | c.1782G>A p.T594= | Silent (SNP) | VAF 18/261 reads (7%) | catalogued as rs778734621, COSV62656595; called by muse, mutect2
- TNR | c.2745G>A p.V915= | Silent (SNP) | VAF 23/654 reads (4%) | catalogued as COSV99692245; called by muse, mutect2
- TRMT44 | c.1281C>T p.L427= | Silent (SNP) | VAF 40/622 reads (6%) | catalogued as rs748550324, COSV101077891; called by muse, mutect2
- UGT2B17 | c.588T>C p.P196= | Silent (SNP) | VAF 29/267 reads (11%) | catalogued as COSV58501049; called by muse, mutect2, varscan2
- ZMYND8 | c.1431C>T p.A477= (on ENST00000311275 / NM_001363741.2; = p.A497= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 111/234 reads (47%) | catalogued as COSV53684156, COSV53688089; called by muse, mutect2, varscan2
- ZNF521 | c.1725T>A p.L575= | Silent (SNP) | VAF 42/230 reads (18%) | catalogued as COSV64123652; called by muse, mutect2, varscan2
- ZNF804A | c.531T>A p.T177= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV56439558; called by muse, mutect2, varscan2
- PIGK | c.987-6786G>C | Intron (SNP) | VAF 128/375 reads (34%) | called by muse, mutect2, varscan2
